Somatic mutation profile of tumor specimen MP2PRT-PAUFWB-TMP1-A (aliquot MP2PRT-PAUFWB-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUFWB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,454 days).
Specimen MP2PRT-PAUFWB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be18f4df-60fb-4154-b38d-09866f971b44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFWB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFWB-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41381804-ea35-4249-8cfc-ba52de476a67

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 76/236 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.5329G>A p.A1777T | Missense Mutation (SNP) | VAF 89/393 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs200939753, CM031283; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CAPN9 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 115/259 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.136); catalogued as rs762312745; called by muse, mutect2, varscan2
- FOXK1 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 113/300 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs762393895; called by muse, mutect2, varscan2
- LTF | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 107/329 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs200930742; called by muse, mutect2
- PTPN11 | c.1504T>C p.S502P | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; called by muse, mutect2, varscan2
- SLC27A6 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs768757659, COSV52479610; called by muse, mutect2, varscan2
- C16orf72 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 217/486 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNGA3 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- IGHJ4 | chr14:105864246 CCAGTAGTCAAAGTAGTCA>GACAC | Missense Mutation (DEL) | VAF 80/94 reads (85%) | called by pindel, varscan2*
- CFAP46 | c.7416C>A p.G2472= | Silent (SNP) | VAF 85/366 reads (23%) | called by muse, mutect2, varscan2
- CLDN16 | c.627C>T p.A209= | Silent (SNP) | VAF 77/300 reads (26%) | catalogued as rs745542693, COSV99289875; called by muse, mutect2, varscan2
- DUSP8 | c.138C>T p.S46= | Silent (SNP) | VAF 58/458 reads (13%) | catalogued as rs1040325649; called by muse, mutect2, varscan2
